CCDI case PBBWFF — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/61ff0fee-c3f6-4a77-9f7d-d0713d3cb4f7

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Dysembryoplastic neuroepithelial tumor: ICD-O-3 morphology code: 9413/0; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 3.7 years (1,345 days).

Biospecimens (3 samples)
- Sample 0DIYS6: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DIYSC: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DIYSI: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
